Gene-level copy-number profile of tumor specimen TCGA-YD-A9TA-06A from TCGA case TCGA-YD-A9TA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.8 years (28,424 days).
Specimen TCGA-YD-A9TA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.2077a743-56ee-4132-a634-dc162de82b87.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YD-A9TA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/11885351-e3e0-4dc0-8f77-64856300104a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 2,747; copy number 2: 14,701; copy number 3: 25,880; copy number 4: 11,068; copy number 5: 2,905; copy number 6: 1,426; copy number 7: 775; copy number 8: 20; copy number 9: 106; copy number 12: 3; copy number 15: 10; copy number 20: 78; copy number 24: 1; copy number 34: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YD-A9TA-06A-11D-A396-01): tumor purity 0.71, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,929,457–30,575,012, 74 genes (broad region; genes not listed).
- chr12:14,914,039–14,981,865, 3 genes: ERP27, ARHGDIB, PDE6H.
- chr17:58,324,472–58,415,766, 1 gene (within-gene range 0–3): TSPOAP1-AS1.
- chr17:58,345,206–58,747,340, 16 genes (within-gene range 0–3): AC004687.2, RNF43, HSF5, SETP3, MTMR4, SEPTIN4-AS1, SEPTIN4, TEX14, U3, IGBP1P2, RNU1-108P, AC011195.1, RNU1-52P, RNVU1-34, RAD51C, AC025521.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 995 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,925,353–43,023,637, 6 genes, copy number 7: SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P, U6.
- chr1:213,428,708–217,137,755, 31 genes, copy number 7 (within-gene range 4–7): RPL31P13, AL592402.1, AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775, SMYD2, AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13, GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG.
- chr3:105,366,909–106,224,375, 3 genes, copy number 7: ALCAM, CBLB, AC131237.1.
- chr3:109,241,507–111,275,563, 20 genes, copy number 8 (within-gene range 6–8): AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3.
- chr3:113,286,930–117,139,389, 51 genes, copy number 9 (within-gene range 3–9): CFAP44, AC026348.1, AC112128.1, CFAP44-AS1, MIR8076, SPICE1, SIDT1, SIDT1-AS1, MIR4446, RN7SL767P, USF3, NAA50, AC108693.1, AC108693.2, ATP6V1A, GRAMD1C, AC079944.1, AC079944.2, VPS26AP1, AC128687.2, ZDHHC23, CCDC191, AC128687.1, AC128687.3, AC092896.1, QTRT2, H2BP3, DRD3, AC093010.1, FAM214BP1, ZNF80, TIGIT, ZBTB20, AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5, ZBTB20-AS2, MIR4796, ZBTB20-AS3, YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3, GAP43, AC092468.1, LSAMP, RN7SL815P, LSAMP-AS1.
- chr5:41,730,065–44,389,706, 57 genes, copy number 7–9 (within-gene range 5–9): OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10.
- chr8:131,712,512–141,195,808, 96 genes, copy number 7 (broad region; genes not listed).
- chr13:33,016,423–92,873,682, 731 genes, copy number 7–34 (within-gene range 3–34) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,035. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
